Somatic mutation profile of tumor specimen C3L-01281-01 (aliquot CPT0079480009) from CPTAC case C3L-01281, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 66.4 years (24,243 days).
Specimen C3L-01281-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3a71f10-cbc9-4de9-ad8f-4540cb45046f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01281-31 (Blood Derived Normal), aliquot CPT0080150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cde27b24-e93b-4be5-bcb5-242c71cfd796

The open-access MAF lists 92 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Frame Shift Del 6, Intron 5, 3'UTR 3, RNA 2, Nonsense Mutation 1, 5'Flank 1, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAK1 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68646360; called by muse, mutect2, varscan2
- CTPS1 | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009345; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2756T>C p.V919A | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV57514919; called by muse, mutect2, varscan2
- GLI3 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 52/622 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs760701023; called by muse, mutect2
- MSX2 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 40/508 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766037353; called by muse, mutect2
- NAA60 | c.108C>T p.I36= | Splice Region (SNP) | VAF 15/116 reads (13%) | catalogued as rs563736586; called by muse, mutect2, varscan2
- OTUD7B | c.2069C>G p.T690S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs782242001; called by muse, mutect2, varscan2
- PCNX1 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762475965; called by muse, mutect2
- RNF17 | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs763054291; called by muse, mutect2, varscan2
- SLC27A1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53097659; called by muse, mutect2
- SNX1 | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99976451; called by muse, mutect2
- SUPT20HL2 | c.1970G>C p.W657S | Missense Mutation (SNP) | VAF 103/208 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200760878; called by muse, mutect2, varscan2
- TRIM14 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1564173010; called by muse, mutect2, varscan2
- VHL | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs869025631, CD141834, CM951280, HM971583, COSV56542714, COSV56543921; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WWC3 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs990932833, COSV66503766; called by muse, varscan2
- ZFYVE26 | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV61326853; called by muse, mutect2, varscan2
- ABCB11 | c.1555G>T p.G519C | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABT1 | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- ACSL3 | c.1859dup p.Y620* | Nonsense Mutation (INS) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.2659C>A p.Q887K | Missense Mutation (SNP) | VAF 57/353 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BTBD7 | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CHD9 | c.5176G>A p.D1726N | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CMTM2 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DGKZ | c.3221T>C p.M1074T (on ENST00000454345 / NM_001105540.2; = p.M886T on NM_003646.4) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DIO3 | c.95T>A p.L32Q | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC8 | c.108_111del p.T38Rfs*8 | Frame Shift Del (DEL) | VAF 21/166 reads (13%) | called by mutect2, pindel, varscan2
- EXOSC8 | c.193-2A>G p.X65_splice | Splice Site (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- FEM1B | c.55A>G p.T19A | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GABRA2 | c.1013_1014del p.T338Kfs*14 | Frame Shift Del (DEL) | VAF 97/399 reads (24%) | called by mutect2, pindel, varscan2
- GLG1 | c.683T>G p.F228C | Missense Mutation (SNP) | VAF 105/388 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HAUS4 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- INSR | c.3547G>T p.D1183Y | Missense Mutation (SNP) | VAF 92/451 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA3 | c.2494T>A p.Y832N | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAL | c.1736A>T p.Q579L | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KANK1 | c.1120del p.M374Cfs*36 | Frame Shift Del (DEL) | VAF 59/270 reads (22%) | called by mutect2, pindel, varscan2
- MIER1 | c.1123G>A p.A375T (on ENST00000355356 / NM_001077701.3; = p.A392T on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/320 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.732); called by muse, varscan2
- MMP15 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MRPL48 | c.528C>G p.S176R | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MTUS2 | c.367A>T p.T123S | Missense Mutation (SNP) | VAF 44/414 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2
- NAT8 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NXPH4 | c.697T>A p.C233S | Missense Mutation (SNP) | VAF 128/436 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PBRM1 | c.1715A>T p.E572V | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP3CA | c.146A>G p.H49R | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRDM2 | c.4969G>A p.A1657T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PRPF8 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 127/434 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PRSS23 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASA1 | c.3141del p.R1047Sfs*54 | Frame Shift Del (DEL) | VAF 117/496 reads (24%) | called by mutect2, pindel, varscan2
- SLC28A1 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 131/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35G2 | c.430C>A p.Q144K | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- STKLD1 | c.1082G>C p.G361A | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); called by muse, mutect2
- STRADB | c.319del p.A107Pfs*2 | Frame Shift Del (DEL) | VAF 38/159 reads (24%) | called by mutect2, pindel, varscan2
- TCF23 | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCP1 | c.1630del p.S544Vfs*38 | Frame Shift Del (DEL) | VAF 51/208 reads (25%) | called by mutect2, pindel, varscan2
- THBS1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNKS2 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNN | c.2491T>A p.Y831N | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.7290G>A p.M2430I | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- WASHC2A | c.3403A>G p.I1135V | Missense Mutation (SNP) | VAF 112/1243 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.401); called by muse, mutect2
- YWHAB | c.717dup p.D240Rfs*31 | Frame Shift Ins (INS) | VAF 30/163 reads (18%) | called by mutect2, pindel, varscan2
- ZFYVE28 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF213 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF239 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- ZNF616 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 99/360 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF92 | c.1171C>T p.H391Y (on ENST00000328747 / NM_152626.4; = p.H322Y on NM_007139.4) | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- AC100868.1 | c.1071G>T p.L357= | Silent (SNP) | VAF 24/294 reads (8%) | called by muse, mutect2
- AMOTL1 | c.42G>T p.A14= | Silent (SNP) | VAF 13/239 reads (5%) | called by muse, mutect2
- ANKRD46 | c.600C>T p.F200= | Silent (SNP) | VAF 30/443 reads (7%) | catalogued as rs751985899; called by muse, mutect2
- CACNA1S | c.2139C>A p.G713= | Silent (SNP) | VAF 52/618 reads (8%) | called by muse, mutect2
- CKAP2 | c.1249A>C p.R417= (on ENST00000378037 / NM_001098525.2; = p.R416= on NM_018204.5) | Silent (SNP) | VAF 72/269 reads (27%) | called by muse, mutect2, varscan2
- DCST1 | c.402C>T p.A134= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV55061150; called by muse, varscan2
- FLRT1 | c.960G>T p.L320= | Silent (SNP) | VAF 78/226 reads (35%) | called by muse, mutect2, varscan2
- FZD5 | c.633G>A p.R211= | Silent (SNP) | VAF 17/322 reads (5%) | called by muse, mutect2
- GPR26 | c.777C>A p.I259= | Silent (SNP) | VAF 8/175 reads (5%) | catalogued as COSV52934864; called by muse, mutect2
- LAMA1 | c.384T>C p.N128= | Silent (SNP) | VAF 95/350 reads (27%) | catalogued as rs1210378011; called by muse, mutect2, varscan2
- MUC4 | c.6126C>A p.S2042= | Silent (SNP) | VAF 36/850 reads (4%) | called by muse, mutect2
- NFKBIA | c.429A>C p.R143= | Silent (SNP) | VAF 26/330 reads (8%) | called by muse, mutect2
- PEX26 | c.447C>A p.A149= | Silent (SNP) | VAF 43/400 reads (11%) | catalogued as COSV61604340; called by muse, mutect2, varscan2
- POC1B | c.396T>C p.Y132= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, varscan2
- SLC5A1 | c.1959G>T p.V653= | Silent (SNP) | VAF 21/503 reads (4%) | called by muse, mutect2
- SNRNP27 | c.282G>A p.E94= | Silent (SNP) | VAF 21/208 reads (10%) | catalogued as rs770322323; called by muse, mutect2, varscan2
- TFF3 | c.168C>T p.C56= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs373136844, COSV52294332; called by muse, mutect2, varscan2
- C3P1 | n.2731C>G | RNA (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- CAPN12 | c.1816-14G>T | Intron (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- CD81 | c.459+13G>C | Intron (SNP) | VAF 23/242 reads (10%) | called by muse, mutect2
- COL11A1 | c.*48C>G | 3'UTR (SNP) | VAF 58/188 reads (31%) | called by muse, varscan2
- CREBZF | c.*243T>A | 3'UTR (SNP) | VAF 54/242 reads (22%) | called by muse, mutect2, varscan2
- GNB5 | c.628-2181T>A | Intron (SNP) | VAF 50/213 reads (23%) | called by muse, mutect2, varscan2
- KLKB1 | c.*18A>G | 3'UTR (SNP) | VAF 91/358 reads (25%) | called by muse, mutect2, varscan2
- MIR498 | n.48G>C | RNA (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- MMAB | chr12:109573521 C>G | 5'Flank (SNP) | VAF 105/386 reads (27%) | called by muse, mutect2, varscan2
- TTC39C | c.167+4836C>T | Intron (SNP) | VAF 19/94 reads (20%) | catalogued as rs141059000; called by muse, mutect2, varscan2
- ZIM2 | c.478-326C>A | Intron (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
